Gene-level copy-number profile of tumor specimen C3N-02188-03 from CPTAC case C3N-02188, project CPTAC-3 (Brain — Gliomas). Sex at birth: male; Vital status: Dead; Primary diagnosis: Glioblastoma; Tissue or organ of origin: Brain, NOS; Age at diagnosis: 59.4 years (21,709 days).
Specimen C3N-02188-03: Sample type: Primary Tumor; Tissue type: Tumor; Tumor descriptor: Primary; Specimen type: Solid Tissue; Biospecimen anatomic site: Brain; Preservation method: Snap Frozen.
Source: NCI Genomic Data Commons open-access Gene Level Copy Number file 68f6a652-2b26-4acc-9a97-f31b592170c8.wgs.ASCAT.gene_level.copy_number_variation.tsv, workflow AscatNGS on whole-genome sequencing of the tumor/normal pair, germline comparator C3N-02188-71 (blood derived normal); Data Release 46.0 - August 10, 2026. Values are absolute (integer) total copy numbers per gene for 60,623 GENCODE v36 genes, of which 1,709 have no estimate.
https://portal.gdc.cancer.gov/files/9b2871b9-e665-4c17-9d7c-92c882ff1cd6

Most common (modal) total copy number across autosomal genes: 2 — the diploid value.
Genes by total copy number (all chromosomes): copy number 0: 24; copy number 1: 5,558; copy number 2: 50,182; copy number 3: 108; copy number 4: 2,916; copy number 5: 1; copy number 6: 1; copy number 10: 108; copy number 50: 9; copy number 59: 7.

Homozygous deletions (total copy number 0; autosomes only): 21 genes in 4 contiguous regions (coordinates GRCh38, first to last gene; gene names only for focal regions of at most 60 genes; where a gene spans a copy-number breakpoint, the lowest–highest segment value inside the gene is given as 'within-gene range'):
- chr6:49,960,249–49,969,625, 2 genes: DEFB114, DEFB113.
- chr9:21,967,752–22,214,672, 8 genes (within-gene range 0–1): CDKN2A, CDKN2B-AS1, AL449423.1, CDKN2B, UBA52P6, AL354709.1, AL354709.2, AL157937.1.
- chr11:67,398,181–67,469,272, 10 genes (within-gene range 0–2): PPP1CA, TBC1D10C, CARNS1, RPS6KB2, RPS6KB2-AS1, PTPRCAP, CORO1B, GPR152, CABP4, TMEM134.
- chr16:87,773,304–87,779,374, 1 gene: AC126696.3.

Amplified relative to the modal value (total copy number ≥ 5, i.e. more than twice the modal value of 2; autosomes only): 126 genes in 4 contiguous regions (coordinates GRCh38, first to last gene; gene names only for focal regions of at most 60 genes; where a gene spans a copy-number breakpoint, the lowest–highest segment value inside the gene is given as 'within-gene range'):
- chr4:51,978,079–57,031,158, 108 genes, copy number 10 (within-gene range 2–10) (broad region; genes not listed).
- chr7:6,754,109–6,799,365, 1 gene, copy number 6 (within-gene range 4–6): RSPH10B2.
- chr7:54,419,444–55,433,742, 16 genes, copy number 50–59: SLC25A5P3, VSTM2A, VSTM2A-OT1, AC011228.1, RNU6-1125P, RPL31P35, SEC61G, SEC61G-DT, AC006971.1, EGFR, EGFR-AS1, ELDR, AC073324.1, CALM1P2, AC073347.1, LANCL2.
- chr14:18,395,626–18,412,264, 1 gene, copy number 5: CR383658.2.

Autosomal genes at a single copy (total copy number 1): 2,711. Sex chromosomes are excluded from the deletion and amplification lists above because the expected copy number there depends on sex.
